Gene-level copy-number profile of tumor specimen 9f905736-f662-41d6-b3ac-16758d from CPTAC case 11LU013, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: GX; Age at diagnosis: 59.2 years (21,627 days).
Specimen 9f905736-f662-41d6-b3ac-16758d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7793713b-560d-4c1d-945d-863a7e03e566.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator c7788b82-8190-4784-ab76-0d1185 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,740 have no estimate.
https://portal.gdc.cancer.gov/files/441aef96-e1eb-43e9-ac91-5e90d1eb4129

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 318; copy number 2: 5,648; copy number 3: 15,621; copy number 4: 17,553; copy number 5: 11,126; copy number 6: 3,781; copy number 7: 1,192; copy number 8: 321; copy number 9: 1,385; copy number 10: 869; copy number 11: 111; copy number 12: 14; copy number 13: 60; copy number 15: 2; copy number 17: 23; copy number 18: 150; copy number 19: 41; copy number 20: 75; copy number 21: 29; copy number 22: 166; copy number 23: 31; copy number 25: 123; copy number 29: 55; copy number 30: 20; copy number 33: 54; copy number 34: 27; copy number 35: 29; copy number 36: 5; copy number 37: 3; copy number 41: 2; copy number 57: 7; copy number 68: 6; copy number 130: 4; copy number 155: 2; copy number 156: 7; copy number 212: 19.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,811,359–143,825,837, 1 gene: AC239798.1.
- chr1:143,955,364–144,068,350, 2 genes: FAM72C, SRGAP2D.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,318 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,498,785–143,500,512, 2 genes, copy number 15: AC239859.2, LINC02799.
- chr1:148,772,640–148,796,325, 2 genes, copy number 13: SEC22B3P, AC245389.1.
- chr7:53,002,420–55,743,457, 47 genes, copy number 41–212: AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2.
- chr8:71,675,300–143,160,711, 997 genes, copy number 9–37 (broad region; genes not listed).
- chr14:18,333,726–41,298,734, 699 genes, copy number 9–10 (broad region; genes not listed).
- chr14:43,990,539–106,879,812, 1,533 genes, copy number 9–12 (broad region; genes not listed).
- chr18:22,347,846–23,026,488, 11 genes, copy number 11 (within-gene range 7–11): AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741.
- chr18:30,713,275–31,760,880, 25 genes, copy number 9: AC090506.1, AC090506.2, AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52.
- chr18:34,225,930–34,226,429, 1 gene, copy number 11: AC104985.2.
- chr20:57,488,392–57,489,027, 1 gene, copy number 10: HMGB1P1.

Autosomal genes at a single copy (total copy number 1): 312. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
